Somatic mutation profile of tumor specimen ALCH-B426-TTP1-A (aliquot ALCH-B426-TTP1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-B426, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 59.9 years (21,868 days).
Specimen ALCH-B426-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9658ed27-a250-488f-a523-2e88b8d93846.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B426-NB1-A (Blood Derived Normal), aliquot ALCH-B426-NB1-A-1-0-D-A80E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/675f6acf-4c9b-4e61-bb10-9192656a76f2

The open-access MAF lists 142 somatic variants for this specimen: 96 protein-altering or splice-affecting, 30 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, Silent 30, Intron 10, Nonsense Mutation 9, Splice Site 3, RNA 2, 3'UTR 2, 5'Flank 1, Splice Region 1, In Frame Del 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BMPR2 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 15/349 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1085307254, CM010162, CM100458, CM1211799; ClinVar: pathogenic; called by muse, mutect2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 41/289 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RAB23 | c.434T>A p.L145* | Nonsense Mutation (SNP) | VAF 18/204 reads (9%) | catalogued as rs121908171, CM071964; ClinVar: pathogenic; called by muse, mutect2
- STK11 | c.374+1A>G p.X125_splice | Splice Site (SNP) | VAF 9/153 reads (6%) | hotspot (GDC flag); catalogued as rs1131690951, CS021376, COSV58820569; ClinVar: pathogenic; called by muse, mutect2
- C4A | c.2571C>G p.N857K | Missense Mutation (SNP) | VAF 26/469 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71177911; called by muse, mutect2
- CASP1 | c.734G>A p.G245E (on ENST00000436863 / NM_033292.4; = p.G224E on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/416 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768484046, COSV100782775; called by muse, mutect2
- CDR1 | c.156G>T p.L52F | Missense Mutation (SNP) | VAF 27/242 reads (11%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.998); catalogued as COSV65164704; called by muse, mutect2, varscan2
- CHCHD4 | c.117G>T p.E39D (on ENST00000396914 / NM_001098502.2; = p.E52D on NM_144636.3) | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV55499909; called by muse, mutect2
- CHST6 | c.116C>A p.A39E | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100178715; called by muse, mutect2, varscan2
- DNAH7 | c.10167G>T p.R3389S | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1459856967, COSV56764349, COSV56773489; called by muse, mutect2, varscan2
- DTNA | c.322A>G p.I108V | Missense Mutation (SNP) | VAF 28/371 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs1201061306; called by muse, mutect2
- FANCB | c.472G>T p.G158C | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.694); catalogued as COSV60761403; called by muse, mutect2
- FCRL2 | c.910C>T p.L304F | Missense Mutation (SNP) | VAF 55/415 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.597); catalogued as rs1210629984; called by muse, mutect2, varscan2
- FLG | c.5254C>A p.R1752S | Missense Mutation (SNP) | VAF 32/466 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as rs746659024, COSV64240072; called by muse, mutect2
- IGFBP3 | c.859A>T p.S287C | Missense Mutation (SNP) | VAF 24/226 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV99298507; called by muse, mutect2, varscan2
- IRF7 | c.753G>A p.W251* (on ENST00000397566; = p.W238* on NM_001572.5) | Nonsense Mutation (SNP) | VAF 10/65 reads (15%) | catalogued as rs1322840804; called by muse, mutect2, varscan2
- MAGEB6 | c.746G>T p.G249V | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66873303; called by muse, mutect2, varscan2
- MYOM3 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 18/223 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as rs563483726, COSV100292216; called by muse, mutect2
- NOTCH1 | c.4845G>T p.M1615I | Missense Mutation (SNP) | VAF 24/213 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as COSV53027674; called by muse, mutect2, varscan2
- PCDHGA7 | c.260C>A p.A87E | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.365); catalogued as rs769758778, COSV99544890; called by muse, mutect2
- PEG3 | c.773-1G>A p.X258_splice | Splice Site (SNP) | VAF 39/292 reads (13%) | catalogued as COSV55641357; called by muse, mutect2, varscan2
- PHKA2 | c.47G>C p.R16P | Missense Mutation (SNP) | VAF 29/443 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV66053597, COSV66056185; called by muse, mutect2
- PLAC8 | c.46G>T p.G16C | Missense Mutation (SNP) | VAF 10/240 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.371); catalogued as rs1270164374; called by muse, mutect2
- PLCD4 | c.505G>T p.E169* | Nonsense Mutation (SNP) | VAF 18/231 reads (8%) | catalogued as COSV68843254; called by muse, mutect2
- PLXNB3 | c.2117G>T p.R706L | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as COSV62801218; called by muse, mutect2
- PNMA8B | c.323G>T p.R108L | Missense Mutation (SNP) | VAF 22/199 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.943); catalogued as COSV66537462; called by muse, mutect2, varscan2
- POT1 | c.416G>T p.W139L | Missense Mutation (SNP) | VAF 21/351 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62930975; called by muse, mutect2
- PUS1 | c.1026G>C p.K342N | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as rs1176704866; called by muse, mutect2, varscan2
- RERE | c.1861A>G p.S621G | Missense Mutation (SNP) | VAF 13/377 reads (3%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.982); catalogued as COSV61942136; called by muse, mutect2
- RREB1 | c.614A>T p.D205V | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV58565260; called by muse, mutect2
- SPATA31D1 | c.2233C>A p.L745I | Missense Mutation (SNP) | VAF 28/503 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.107); catalogued as COSV61199472; called by muse, mutect2
- STKLD1 | c.848C>A p.S283* | Nonsense Mutation (SNP) | VAF 16/91 reads (18%) | catalogued as COSV100912031; called by muse, mutect2, varscan2
- TBC1D32 | c.3382A>T p.T1128S | Missense Mutation (SNP) | VAF 15/182 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.075); catalogued as COSV99249720; called by muse, mutect2
- TENM1 | c.209C>G p.S70C | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV100950277; called by muse, varscan2
- TMED9 | c.103G>T p.G35* | Nonsense Mutation (SNP) | VAF 8/244 reads (3%) | catalogued as COSV60264141; called by muse, mutect2
- TRAV24 | c.157T>C p.Y53H | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.877); catalogued as rs1178898155; called by muse, mutect2
- TTI2 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 29/356 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1274164834; called by muse, mutect2
- WDFY3 | c.9397G>C p.A3133P | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.282); catalogued as COSV55713901; called by muse, mutect2, varscan2
- AC242842.3 | c.2672T>G p.M891R | Missense Mutation (SNP) | VAF 35/200 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- ACKR1 | c.729G>T p.M243I | Missense Mutation (SNP) | VAF 45/223 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- AMIGO1 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 32/394 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- APBA2 | c.749C>A p.P250H | Missense Mutation (SNP) | VAF 18/328 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- CAND1 | c.76G>T p.A26S | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CHL1 | c.3253G>A p.G1085R (on ENST00000397491 / NM_001253387.1; = p.G1101R on NM_006614.4) | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CHRM1 | c.592T>C p.Y198H | Missense Mutation (SNP) | VAF 24/288 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CLOCK | c.2042G>C p.S681T | Missense Mutation (SNP) | VAF 27/270 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CLSPN | c.350A>G p.K117R | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.079); called by muse, mutect2
- CNTN2 | c.1927C>G p.L643V | Missense Mutation (SNP) | VAF 35/278 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- COLEC12 | c.208G>T p.G70C | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.219); called by muse, mutect2
- CUBN | c.1837G>T p.G613* | Nonsense Mutation (SNP) | VAF 15/244 reads (6%) | called by muse, mutect2
- DACT1 | c.1095C>G p.D365E | Missense Mutation (SNP) | VAF 20/331 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2
- DCAF12 | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 46/492 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.332); called by muse, mutect2
- DGKD | c.1393A>C p.T465P (on ENST00000264057 / NM_152879.3; = p.T421P on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/225 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2
- DNAH12 | c.8729C>T p.P2910L (on ENST00000351747; = p.P3778L on NM_001366028.2) | Missense Mutation (SNP) | VAF 14/292 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- DYNC2H1 | c.5916G>T p.R1972S | Missense Mutation (SNP) | VAF 20/193 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPHB4 | c.2228C>A p.A743D | Missense Mutation (SNP) | VAF 25/416 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAM3D | c.374-2A>G p.X125_splice | Splice Site (SNP) | VAF 14/192 reads (7%) | called by muse, mutect2
- FLI1 | c.100A>C p.M34L | Missense Mutation (SNP) | VAF 20/264 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.268); called by muse, mutect2
- GIMD1 | c.37C>G p.L13V | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.098); called by muse, mutect2
- IHH | c.815C>A p.T272K | Missense Mutation (SNP) | VAF 25/315 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IL17RC | c.1279C>T p.L427F (on ENST00000295981 / NM_153461.4; = p.L341F on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.216); called by muse, mutect2
- KCTD9 | c.556G>T p.V186L | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2
- KRT2 | c.1379T>A p.L460Q | Missense Mutation (SNP) | VAF 13/416 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KRT4 | c.1490G>T p.G497V | Missense Mutation (SNP) | VAF 43/347 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- LETM2 | c.587T>A p.V196E (on ENST00000379957 / NM_001286819.2; = p.V149E on NM_001199659.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); called by muse, varscan2
- MACROH2A1 | c.798T>A p.H266Q (on ENST00000510038; = p.H265Q on NM_004893.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.474); called by muse, mutect2
- MDN1 | c.10510C>A p.L3504I | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- MUC21 | c.1694G>T p.G565V | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.235); called by muse, varscan2
- MYH7 | c.2932C>A p.L978M | Missense Mutation (SNP) | VAF 55/446 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- MYO15A | c.201_229del p.Q68Hfs*150 | Frame Shift Del (DEL) | VAF 26/320 reads (8%) | called by mutect2, pindel
- MYO18B | c.7189C>A p.P2397T | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- NBEAL2 | c.4914G>T p.L1638F | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.084); called by muse, mutect2
- NBEAL2 | c.4915G>T p.E1639* | Nonsense Mutation (SNP) | VAF 12/142 reads (8%) | called by muse, mutect2
- NEK8 | c.1406G>T p.R469L | Missense Mutation (SNP) | VAF 21/244 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.11); called by muse, mutect2
- NEU4 | c.537C>A p.Y179* (on ENST00000391969 / NM_001167602.3; = p.Y191* on NM_080741.4) | Nonsense Mutation (SNP) | VAF 20/154 reads (13%) | called by muse, mutect2, varscan2
- NLRP11 | c.1816G>T p.E606* | Nonsense Mutation (SNP) | VAF 5/53 reads (9%) | called by muse, mutect2
- NMT2 | c.1151T>C p.I384T | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- NPAS1 | c.1547C>A p.P516H | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.431); called by muse, mutect2
- OTOGL | c.4745A>G p.N1582S (on ENST00000547103; = p.N1573S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCDH11X | c.753G>C p.E251D | Missense Mutation (SNP) | VAF 25/237 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PLA2G4A | c.930_935del p.T311_L312del | In Frame Del (DEL) | VAF 14/126 reads (11%) | called by mutect2, pindel, varscan2
- POTEC | c.1140G>T p.K380N | Missense Mutation (SNP) | VAF 17/236 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.186); called by muse, mutect2
- PPP1R3F | c.1915A>T p.I639F | Missense Mutation (SNP) | VAF 22/231 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2
- PTPRZ1 | c.1780T>C p.S594P | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- RELN | c.2604C>A p.S868R | Missense Mutation (SNP) | VAF 23/241 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- SCLT1 | c.986C>T p.A329V | Missense Mutation (SNP) | VAF 8/210 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- SDHC | c.177C>T p.Y59= | Splice Region (SNP) | VAF 11/271 reads (4%) | called by muse, mutect2
- SLC25A5 | c.537delinsTT p.S180Ffs*17 | Frame Shift Ins (INS) | VAF 14/152 reads (9%) | called by pindel, varscan2*
- SPATC1 | c.1615C>A p.P539T | Missense Mutation (SNP) | VAF 35/320 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- TAS2R60 | c.191C>G p.A64G | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TENM1 | c.2105A>T p.H702L | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); called by muse, mutect2
- TEX44 | c.37G>C p.D13H | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.486); called by muse, mutect2
- TMEM104 | c.218A>G p.Q73R | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0.01); called by muse, mutect2
- TRPC4 | c.730C>A p.L244M | Missense Mutation (SNP) | VAF 11/260 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2
- WNT6 | c.347C>G p.A116G | Missense Mutation (SNP) | VAF 13/180 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.222); called by muse, mutect2
- ZEB1 | c.1220T>C p.I407T | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.9); called by muse, mutect2
- ADAMTS1 | c.2082A>G p.G694= | Silent (SNP) | VAF 10/210 reads (5%) | catalogued as COSV99535920; called by muse, mutect2
- CDHR1 | c.828C>A p.G276= | Silent (SNP) | VAF 23/266 reads (9%) | called by muse, mutect2
- CNTN2 | c.1926C>A p.T642= | Silent (SNP) | VAF 34/282 reads (12%) | catalogued as rs747563076; called by muse, mutect2, varscan2
- DMRTB1 | c.495G>A p.E165= | Silent (SNP) | VAF 12/184 reads (7%) | called by muse, mutect2
- FOXC1 | c.900G>A p.P300= | Silent (SNP) | VAF 15/124 reads (12%) | catalogued as rs776930290; called by muse, mutect2, varscan2
- HELZ2 | c.4686G>A p.Q1562= (on ENST00000467148 / NM_001037335.2; = p.Q993= on NM_033405.3) | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV101427591; called by muse, mutect2
- HOXC8 | c.336C>G p.P112= | Silent (SNP) | VAF 46/315 reads (15%) | catalogued as rs1300124197; called by muse, mutect2, varscan2
- HSD17B14 | c.426G>A p.L142= | Silent (SNP) | VAF 20/296 reads (7%) | catalogued as COSV54412330; called by muse, mutect2
- ITPRID1 | c.1272C>T p.S424= | Silent (SNP) | VAF 15/187 reads (8%) | catalogued as rs370130726; called by muse, mutect2
- LTBP1 | c.1443C>T p.N481= (on ENST00000404816 / NM_206943.4; = p.N155= on NM_000627.4) | Silent (SNP) | VAF 10/82 reads (12%) | called by muse, mutect2, varscan2
- MMP26 | c.51C>A p.A17= | Silent (SNP) | VAF 48/652 reads (7%) | called by muse, mutect2
- MUC2 | c.1035C>T p.C345= | Silent (SNP) | VAF 18/156 reads (12%) | catalogued as rs372884289; called by muse, mutect2, varscan2
- MYH7 | c.4500G>A p.R1500= | Silent (SNP) | VAF 42/327 reads (13%) | catalogued as rs199995198, COSV62517394, COSV62522791; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR52N2 | c.195G>T p.L65= | Silent (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2
- OR5D13 | c.753T>G p.T251= | Silent (SNP) | VAF 8/71 reads (11%) | called by muse, mutect2, varscan2
- OR5L2 | c.792A>T p.S264= | Silent (SNP) | VAF 22/352 reads (6%) | called by muse, mutect2
- PCDH15 | c.966C>A p.I322= | Silent (SNP) | VAF 20/342 reads (6%) | called by muse, mutect2
- PCDHB14 | c.1479C>T p.P493= | Silent (SNP) | VAF 22/405 reads (5%) | called by muse, mutect2
- PLAT | c.1071C>T p.H357= | Silent (SNP) | VAF 32/323 reads (10%) | catalogued as rs1564126800; called by muse, mutect2, varscan2
- RGR | c.93C>T p.L31= | Silent (SNP) | VAF 27/442 reads (6%) | called by muse, mutect2
- RTTN | c.642C>T p.I214= | Silent (SNP) | VAF 17/218 reads (8%) | catalogued as rs530941846; called by muse, mutect2
- RYR3 | c.7428G>A p.L2476= (on ENST00000389232; = p.L2477= on NM_001036.6) | Silent (SNP) | VAF 16/208 reads (8%) | catalogued as rs1369436276; called by muse, mutect2
- SH2B1 | c.240G>T p.V80= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- SLC25A48 | c.309G>T p.L103= | Silent (SNP) | VAF 16/246 reads (7%) | called by muse, mutect2
- TNXB | c.6723C>A p.T2241= (on ENST00000647633; = p.T1994= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/178 reads (12%) | called by muse, mutect2, varscan2
- TROAP | c.1323G>A p.L441= | Silent (SNP) | VAF 12/88 reads (14%) | called by muse, mutect2
- VAC14 | c.1605C>T p.L535= | Silent (SNP) | VAF 19/174 reads (11%) | called by muse, mutect2, varscan2
- WNT3A | c.180G>T p.V60= | Silent (SNP) | VAF 36/253 reads (14%) | called by muse, mutect2, varscan2
- ZFHX4 | c.8064G>T p.S2688= | Silent (SNP) | VAF 18/330 reads (5%) | catalogued as COSV51472767, COSV51500973; called by muse, mutect2
- ZNF831 | c.201T>A p.P67= | Silent (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2, varscan2
- AC134312.1 | n.414C>A | RNA (SNP) | VAF 11/83 reads (13%) | called by muse, mutect2, varscan2
- AC244517.10 | c.36-9746C>G | Intron (SNP) | VAF 7/105 reads (7%) | called by muse, mutect2
- ASH1L | chr1:155563264 C>G | 5'Flank (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- BCAP31 | c.-44-302G>A | Intron (SNP) | VAF 11/174 reads (6%) | called by muse, mutect2
- EHD2 | c.*489del | 3'UTR (DEL) | VAF 19/189 reads (10%) | called by mutect2, pindel, varscan2
- F8 | c.6429+9871G>T | Intron (SNP) | VAF 20/183 reads (11%) | called by mutect2, varscan2
- FBLN1 | c.1698-11376G>T | Intron (SNP) | VAF 10/108 reads (9%) | called by muse, mutect2
- GPI | c.1474+41G>T | Intron (SNP) | VAF 63/464 reads (14%) | called by muse, mutect2, varscan2
- MARCHF1 | c.242+542G>T | Intron (SNP) | VAF 7/91 reads (8%) | called by muse, mutect2
- NOC2LP2 | n.979C>A | RNA (SNP) | VAF 38/339 reads (11%) | called by muse, mutect2, varscan2
- OR9Q1 | c.-15+53152G>A | Intron (SNP) | VAF 14/115 reads (12%) | called by mutect2, varscan2
- PCDHA10 | c.2388+4684C>T | Intron (SNP) | VAF 13/171 reads (8%) | catalogued as COSV56507334; called by muse, mutect2
- PPDPFL | c.*689G>A | 3'UTR (SNP) | VAF 28/442 reads (6%) | catalogued as rs1440767359; called by muse, mutect2
- PTPRR | c.1498-10295G>A | Intron (SNP) | VAF 45/321 reads (14%) | catalogued as rs1041818005; called by muse, mutect2, varscan2
- SCFD2 | c.1562-35334G>T | Intron (SNP) | VAF 32/302 reads (11%) | called by muse, mutect2, varscan2
- SLITRK2 | chrX:145827816 G>C | 3'Flank (SNP) | VAF 18/200 reads (9%) | catalogued as COSV59422730; called by muse, mutect2
